Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7610, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7610-01A (Primary Tumor).

Microscopic

Sections demonstrate a moderately hypercellular glial neoplasm, the cells of which have round nuclei, often with perinuclear halos. A minority population of small fibrillary astrocytes is also seen. There is little atypia and no mitotic figures are seen. There is no microvascular proliferation or necrosis. The tumor diffusely infiltrates both gray and white matter.

Addendum

Scattered MIB-1 reactive cells are present with a labeling index of 2.2%. This is indicative of a modestly proliferative neoplasm and is consistent with the low grade histologic features.

Diagnosis

Low grade oligoastrocytoma. Oligodendroglioma predominant

Source: NCI Genomic Data Commons file d17470ba-e655-412b-9918-b85fca13b141 (TCGA-HT-7610.F33A23FF-73C6-4AEA-A9C0-9A794368DDC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).